Somatic mutation profile of tumor specimen TARGET-20-PARJLW-09A (aliquot TARGET-20-PARJLW-09A-01D) from TARGET case TARGET-20-PARJLW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,819 days).
Specimen TARGET-20-PARJLW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05a69af7-fe2c-4f4f-9ea3-3d19cc5912dc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARJLW-14A (Bone Marrow Normal), aliquot TARGET-20-PARJLW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3933bfc-dbb9-4671-bfe9-21f516dc80c8

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 113/302 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 26/48 reads (54%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- WT1 | c.1231T>C p.C411R | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM041492; called by muse, mutect2, varscan2
- ANKRD30A | c.1820T>C p.L607P (on ENST00000611781; = p.L551P on NM_052997.2) | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.944); called by muse, mutect2
